Somatic mutation profile of tumor specimen TCGA-A6-2685-01A (aliquot TCGA-A6-2685-01A-01D-1408-10) from TCGA case TCGA-A6-2685, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 48.6 years (17,757 days).
Specimen TCGA-A6-2685-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b10c1125-ddb9-46ce-a372-41b0e474f47f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2685-10A (Blood Derived Normal), aliquot TCGA-A6-2685-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ada383f3-73fc-473e-bca7-2cad5ff4519b

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 3, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.3480G>T p.K1160N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100252433; called by muse, mutect2, varscan2
- ADORA2A | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs200937140, COSV100418057, COSV58378856; called by muse, mutect2, varscan2
- CACNA2D1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.543); catalogued as rs1386978066, COSV62380453; called by muse, mutect2, varscan2
- CCDC105 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1363224809, COSV52963869; called by muse, mutect2, varscan2
- CCDC114 | c.1430C>G p.P477R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59554989, COSV59558817; called by muse, mutect2, varscan2
- DCPS | c.204G>T p.V68= | Splice Region (SNP) | VAF 13/66 reads (20%) | catalogued as rs1381681891, COSV99703400; called by muse, mutect2, varscan2
- DEFB135 | c.203C>A p.P68Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV101198539; called by muse, mutect2, varscan2
- DNAH5 | c.13730G>A p.R4577Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs759563638, COSV54205926, COSV99447576; called by muse, mutect2, varscan2
- EIF5B | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV99177030; called by muse, mutect2, varscan2
- FAM47B | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1003154042, COSV61453303, COSV61453412; called by muse, mutect2, varscan2
- FGD3 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61595354; called by muse, mutect2, varscan2
- FRMD4A | c.2862C>G p.D954E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100661597; called by muse, mutect2, varscan2
- GDPD4 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV60016782; called by muse, mutect2, varscan2
- HHAT | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs376491664; called by muse, mutect2, varscan2
- HTR3E | c.1054C>T p.L352F (on ENST00000415389 / NM_001256613.1; = p.L367F on NM_182589.2) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100093890; called by muse, mutect2, varscan2
- INPP5A | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV100704254; called by muse, mutect2, varscan2
- MAGEA1 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as COSV100756629; called by muse, mutect2, varscan2
- MAP2K7 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67607630; called by muse, mutect2, varscan2
- MAP3K19 | c.3111G>T p.E1037D | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100208336; called by muse, mutect2, varscan2
- MEIOC | c.1432T>C p.W478R | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100740192; called by muse, mutect2, varscan2
- NDST2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs141489511; called by mutect2, varscan2
- NEXMIF | c.3191G>A p.R1064H | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770464262, COSV50029704; called by muse, mutect2, varscan2
- NHLH1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as COSV100131436; called by muse, mutect2, varscan2
- OR2L3 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV100741945; called by muse, mutect2
- PCDHGC4 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99339132; called by muse, mutect2, varscan2
- PCLO | c.10453C>A p.P3485T | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV61612855; called by muse, mutect2, varscan2
- PIP4P2 | c.323A>T p.K108M | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99575253; called by muse, mutect2, varscan2
- PLXNA1 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as COSV99302707; called by muse, mutect2, varscan2
- RBPJL | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759319898, COSV59216638; called by muse, mutect2, varscan2
- SAMD9L | c.4687G>C p.E1563Q | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV100560539; called by muse, mutect2, varscan2
- SCARB1 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99909074; called by muse, mutect2, varscan2
- SIGLEC10 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs772709558, COSV100218722; called by muse, mutect2, varscan2
- STK32A | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100096867; called by muse, mutect2
- TADA3 | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1404776921, COSV99809453; called by muse, mutect2, varscan2
- TCF25 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); catalogued as rs747448389, COSV54533580; called by muse, mutect2, varscan2
- TENM1 | c.6763C>T p.R2255* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV64426961; called by muse, mutect2, varscan2
- TFAP2D | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99145814; called by muse, mutect2, varscan2
- LRRC41 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CASP2 | c.1125C>T p.A375= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs1396682002, COSV100130937; called by muse, mutect2, varscan2
- CD48 | c.612C>T p.S204= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs1200744694, COSV100924204; called by muse, mutect2, varscan2
- CLDN25 | c.546C>T p.L182= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV101493588, COSV71620415; called by muse, mutect2, varscan2
- CTSF | c.1194C>G p.G398= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100074215; called by muse, mutect2, varscan2
- DAB2 | c.1185G>A p.P395= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs781429014, COSV57913298; called by muse, mutect2, varscan2
- GPX6 | c.570C>T p.P190= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs767179494, COSV100724794; called by muse, mutect2, varscan2
- KNDC1 | c.669C>T p.N223= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs754168076, COSV100464127; called by muse, mutect2, varscan2
- MTMR12 | c.1548G>A p.L516= | Silent (SNP) | VAF 61/175 reads (35%) | catalogued as COSV99373488; called by muse, mutect2, varscan2
- NLRP5 | c.783G>A p.P261= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs991541099, COSV66761752; called by muse, mutect2, varscan2
- PARD6B | c.999C>A p.G333= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV100859902; called by muse, mutect2, varscan2
- SNCAIP | c.2121C>T p.S707= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs146249796, COSV54411323; called by muse, mutect2, varscan2
- TECR | c.660C>T p.P220= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1477289902, COSV99295049; called by muse, mutect2, varscan2
- MIR299 | n.16G>A | RNA (SNP) | VAF 6/35 reads (17%) | catalogued as rs374292470; called by muse, mutect2, varscan2
